Somatic mutation profile of tumor specimen TCGA-60-2698-01A (aliquot TCGA-60-2698-01A-01D-1522-08) from TCGA case TCGA-60-2698, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.4 years (22,800 days).
Specimen TCGA-60-2698-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1f1bb81-db32-416b-b428-af91182a0297.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2698-11A (Solid Tissue Normal), aliquot TCGA-60-2698-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9316b290-f5fa-4450-8210-aa36354fb435

The open-access MAF lists 1,135 somatic variants for this specimen: 859 protein-altering or splice-affecting, 247 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 743, Silent 247, Nonsense Mutation 78, Frame Shift Del 15, Splice Site 13, Intron 11, RNA 10, 5'UTR 4, Splice Region 4, Nonstop Mutation 2, Frame Shift Ins 2, 3'Flank 2.

Variants (750 of 1,135; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.515C>G p.S172C | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs1407810587, COSV52708092; called by muse, mutect2, varscan2
- AASS | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV62790735; called by muse, mutect2, varscan2
- ABCB1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55955416; called by muse, mutect2, varscan2
- ABCB1 | c.579C>G p.F193L | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as rs770008344, COSV55955423; called by muse, mutect2, varscan2
- ABCD2 | c.1678C>G p.Q560E | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1389158925, COSV58052864; called by muse, mutect2, varscan2
- ABL1 | c.2576C>G p.S859* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV59334680; called by muse, mutect2, varscan2
- AC004593.2 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as rs934664832, COSV56095903; called by muse, mutect2
- AC011448.1 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs769884525, COSV53064293; called by muse, mutect2
- ACAD9 | c.1791G>C p.Q597H | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV58308540; called by muse, mutect2, varscan2
- ACOX3 | c.1232C>G p.A411G | Missense Mutation (SNP) | VAF 21/508 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV62712613; called by muse, mutect2
- ACSL6 | c.794del p.P265Rfs*37 (on ENST00000379240; = p.P290Rfs*37 on NM_015256.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as COSV57297826; called by mutect2, pindel, varscan2
- ACTL8 | c.880C>G p.H294D | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV64861916, COSV64862853; called by muse, mutect2, varscan2
- ADAM10 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53052740; called by muse, mutect2, varscan2
- ADAM23 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs906482356, COSV52213597, COSV52214832, COSV52220227; called by muse, mutect2, varscan2
- ADAM7 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as COSV51542422; called by muse, mutect2, varscan2
- ADAMTS10 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.603); catalogued as COSV54356382; called by muse, mutect2
- ADAMTS12 | c.4063G>T p.D1355Y | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100711651, COSV61257949, COSV61268012; called by muse, mutect2, varscan2
- ADAMTS12 | c.3971A>T p.E1324V | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV61268024; called by muse, mutect2, varscan2
- ADAMTS16 | c.1930A>C p.S644R | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs777183350, COSV56995789; called by muse, mutect2, varscan2
- ADAMTS3 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV54395451; called by muse, mutect2, varscan2
- ADAMTS6 | c.2114G>A p.R705K | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV66861605; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2939A>T p.Y980F | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54455715; called by muse, mutect2, varscan2
- ADGRB3 | c.4012G>T p.E1338* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | catalogued as COSV53251086; called by muse, mutect2, varscan2
- ADGRD1 | c.2053C>G p.L685V | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV55449658; called by muse, mutect2, varscan2
- ADGRE1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV51677645; called by muse, mutect2, varscan2
- ADGRG7 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56298412, COSV56298546; called by muse, mutect2, varscan2
- ADGRL4 | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV66062734; called by muse, mutect2, varscan2
- ADGRV1 | c.17279G>A p.G5760E | Missense Mutation (SNP) | VAF 119/224 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67989140; called by muse, mutect2, varscan2
- AHI1 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55623723; called by muse, mutect2
- AKAP3 | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV50539351; called by muse, mutect2, varscan2
- AKR1B10 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV62055631, COSV62055914; called by muse, mutect2, varscan2
- AL121899.2 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1264352447, COSV67351259; called by muse, mutect2, varscan2
- ALCAM | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60250848; called by muse, mutect2, varscan2
- ALDH1A2 | c.1485G>T p.M495I | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV51084322; called by muse, mutect2, varscan2
- ALDH1A2 | c.1485-1G>A p.X495_splice | Splice Site (SNP) | VAF 45/214 reads (21%) | catalogued as COSV99991197; called by muse, mutect2, varscan2
- ALG8 | c.285G>C p.L95F | Missense Mutation (SNP) | VAF 15/382 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55201152; called by muse, mutect2
- AMER3 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58467956; called by muse, mutect2, varscan2
- ANGPT2 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 18/196 reads (9%) | catalogued as COSV57338139; called by muse, mutect2
- ANK3 | c.7202A>T p.E2401V | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55066348; called by muse, mutect2, varscan2
- ANKRD12 | c.4994A>C p.N1665T | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV50832513; called by muse, mutect2, varscan2
- ANKRD12 | c.5710C>T p.R1904* | Nonsense Mutation (SNP) | VAF 29/240 reads (12%) | catalogued as rs891449557, COSV50832535; called by muse, mutect2, varscan2
- ANKRD13B | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV67474103; called by muse, mutect2, varscan2
- ANKRD30A | c.3487C>T p.Q1163* (on ENST00000611781; = p.Q1107* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 157/394 reads (40%) | catalogued as rs1436766225, COSV100653796, COSV64614228; called by muse, varscan2
- APBA2 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV67105146; called by muse, mutect2, varscan2
- APPL1 | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV55701849; called by muse, mutect2, varscan2
- AQP5 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781095987, COSV52230869, COSV99527496; called by muse, mutect2, varscan2
- ARAF | c.711G>C p.Q237H | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV51693612; called by muse, mutect2, varscan2
- ARHGAP21 | c.3166C>T p.R1056* | Nonsense Mutation (SNP) | VAF 33/272 reads (12%) | catalogued as COSV57602405; called by muse, mutect2, varscan2
- ARID1B | c.5362G>C p.D1788H | Missense Mutation (SNP) | VAF 150/559 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV51668705, COSV51674034; called by muse, mutect2, varscan2
- ARID2 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.112); catalogued as COSV57608330; called by muse, mutect2, varscan2
- ARID2 | c.3298C>G p.Q1100E | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV57601004, COSV57608342; called by muse, mutect2
- ARL6 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 30/178 reads (17%) | catalogued as COSV60117994; called by muse, mutect2, varscan2
- ARMC7 | c.200C>G p.S67W | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1215933066, COSV55461200; called by muse, mutect2, varscan2
- ARMH4 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV50767350, COSV99958351; called by muse, mutect2, varscan2
- ASB11 | c.452T>A p.L151Q | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV60355691; called by muse, mutect2, varscan2
- ASCC3 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61230646; called by muse, mutect2
- ASH1L | c.3326C>A p.S1109Y | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as COSV64210064; called by muse, mutect2, varscan2
- ASIC2 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs757867324, COSV56765303, COSV99859063; called by muse, mutect2, varscan2
- ASPH | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV62860209; called by muse, mutect2, varscan2
- ATAD2 | c.2206G>C p.D736H | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54883185; called by muse, mutect2, varscan2
- ATAD5 | c.2794-1G>T p.X932_splice | Splice Site (SNP) | VAF 28/147 reads (19%) | catalogued as COSV58976179; called by muse, mutect2, varscan2
- ATP10A | c.497del p.G166Efs*41 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | catalogued as COSV63518896; called by mutect2, pindel, varscan2
- ATP11A | c.3086G>C p.W1029S | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV52115915; called by muse, mutect2, varscan2
- ATP2A3 | c.1340G>T p.C447F | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV59231253; called by muse, mutect2, varscan2
- ATP6V0A4 | c.351G>C p.L117F | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59477480; called by muse, mutect2, varscan2
- ATXN7 | c.590G>C p.G197A | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1559654831, COSV55752761; called by muse, mutect2
- AVPR1B | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 46/143 reads (32%) | catalogued as COSV65638311; called by muse, mutect2, varscan2
- AXDND1 | c.1199G>C p.W400S | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62644664; called by muse, mutect2, varscan2
- B3GALT2 | c.637C>G p.H213D | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV66464283; called by muse, mutect2, varscan2
- BARD1 | c.1980C>G p.S660R | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53613664; called by muse, mutect2, varscan2
- BBOX1 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV54192138; called by muse, mutect2
- BCHE | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52258840; called by muse, mutect2
- BCL6 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.253); catalogued as COSV51653431; called by muse, mutect2, varscan2
- BIRC6 | c.4606G>T p.D1536Y | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs769833188, COSV70202113; called by muse, mutect2, varscan2
- BIRC7 | c.820G>A p.E274K (on ENST00000217169 / NM_139317.3; = p.E256K on NM_022161.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV53901851; called by muse, mutect2, varscan2
- BMPER | c.1552G>C p.D518H | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as rs750210912, COSV51819440, COSV51823831; called by muse, mutect2, varscan2
- BPIFB4 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1191459280, COSV64951615; called by muse, mutect2
- BRPF3 | c.403G>C p.A135P | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.825); catalogued as COSV100325551, COSV60208258; called by muse, mutect2, varscan2
- BRWD1 | c.6818C>G p.S2273C | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as COSV59000362, COSV59000786; called by muse, mutect2, varscan2
- BRWD3 | c.4462C>T p.H1488Y | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64750342; called by muse, mutect2, varscan2
- BTK | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 121/206 reads (59%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as CM980267, COSV58121433; called by muse, mutect2, varscan2
- BTN3A2 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62687651; called by muse, mutect2
- BTRC | c.445C>T p.Q149* (on ENST00000370187 / NM_033637.4; = p.Q113* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 7/148 reads (5%) | catalogued as COSV64562060; called by muse, mutect2
- BYSL | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.042); catalogued as COSV57828914; called by muse, mutect2, varscan2
- C12orf50 | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV53894759, COSV53896658; called by muse, mutect2, varscan2
- C12orf50 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV53895860, COSV53896425; called by muse, mutect2, varscan2
- C1orf100 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV57373251; called by muse, mutect2, varscan2
- C1orf141 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 48/324 reads (15%) | catalogued as COSV63992921; called by muse, mutect2, varscan2
- C2orf16 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV62676761; called by muse, mutect2, varscan2
- C2orf78 | c.2051C>A p.P684Q | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs756767934, COSV101280987, COSV68518293; called by muse, mutect2, varscan2
- C4orf51 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 43/126 reads (34%) | catalogued as COSV71264425; called by muse, mutect2, varscan2
- C6orf118 | c.490C>G p.P164A | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV57814483, COSV57816483; called by muse, mutect2, varscan2
- C6orf226 | c.157C>G p.R53G | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.133); catalogued as COSV59035017; called by muse, varscan2
- C7orf50 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV62476153; called by muse, mutect2
- CA10 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV53354543, COSV53357617; called by muse, mutect2, varscan2
- CACHD1 | c.3476G>C p.R1159T | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.916); catalogued as COSV51556102; called by muse, mutect2
- CACNA1G | c.5452G>C p.E1818Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as COSV61731412; called by muse, mutect2
- CARS1 | c.1612A>G p.R538G | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV53456656; called by muse, mutect2, varscan2
- CASP10 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.476); catalogued as COSV53779261; called by muse, mutect2, varscan2
- CASP2 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV60082693; called by muse, mutect2, varscan2
- CATSPER3 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV50947512; called by muse, mutect2, varscan2
- CAV3 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as rs773309037, COSV57479778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCAR1 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 60/205 reads (29%) | catalogued as COSV56271340; called by muse, mutect2, varscan2
- CCDC112 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV65473496; called by muse, mutect2, varscan2
- CCDC113 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1034980690, COSV54686714; called by muse, mutect2
- CCDC146 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53550951; called by muse, mutect2
- CCDC170 | c.1861A>G p.R621G | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53342767, COSV53345757; called by muse, mutect2, varscan2
- CCDC191 | c.2148G>C p.K716N | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs888443284, COSV55673772; called by muse, mutect2, varscan2
- CCDC24 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV58844510; called by muse, mutect2, varscan2
- CCDC47 | c.372+1G>C p.X124_splice | Splice Site (SNP) | VAF 26/186 reads (14%) | catalogued as COSV56723555; called by muse, mutect2, varscan2
- CCDC51 | c.933G>C p.R311S | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV56491560; called by muse, mutect2, varscan2
- CCL3 | c.101G>C p.C34S | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190805628; called by muse, varscan2
- CCPG1 | c.1981C>T p.Q661* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | catalogued as COSV51242573; called by muse, mutect2, varscan2
- CCPG1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV60526317; called by muse, mutect2, varscan2
- CCR4 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 29/442 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.904); catalogued as COSV58382880; called by muse, mutect2
- CCSER1 | c.1798A>T p.S600C | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61443743; called by muse, varscan2
- CD163L1 | c.3709G>C p.E1237Q | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58010384, COSV58019196; called by muse, mutect2, varscan2
- CD163L1 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 8/260 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV58019209; called by muse, mutect2
- CD36 | c.845A>C p.D282A | Missense Mutation (SNP) | VAF 250/632 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV59215204; called by muse, mutect2, varscan2
- CD99L2 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 57/106 reads (54%) | catalogued as COSV100692040, COSV60937141; called by muse, mutect2, varscan2
- CDAN1 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51166623; called by muse, mutect2, varscan2
- CDC42BPB | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); catalogued as COSV63474689; called by muse, mutect2
- CDC42BPG | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61348133; called by muse, mutect2, varscan2
- CDC5L | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65176548; called by muse, mutect2, varscan2
- CDH12 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 31/334 reads (9%) | catalogued as COSV66419682; called by muse, mutect2, varscan2
- CDH18 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs779360240, COSV56936318; called by muse, mutect2, varscan2
- CDH19 | c.1451C>A p.S484Y | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV50964206; called by muse, mutect2, varscan2
- CDK13 | c.2752C>G p.Q918E | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as COSV51702651; called by muse, mutect2, varscan2
- CDK13 | c.4160C>T p.S1387F | Missense Mutation (SNP) | VAF 209/496 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV51702659; called by muse, mutect2, varscan2
- CDK19 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV60450790; called by muse, mutect2, varscan2
- CDKN2A | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV58703319; called by muse, varscan2
- CDON | c.2248C>G p.P750A | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749742672, COSV54999681; called by muse, mutect2, varscan2
- CDYL2 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73654364; called by muse, mutect2, varscan2
- CEACAM8 | c.29G>T p.R10I | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV54991077; called by muse, mutect2, varscan2
- CENPF | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 48/171 reads (28%) | catalogued as COSV104423678, COSV65276282; called by muse, mutect2, varscan2
- CENPI | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 118/184 reads (64%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.747); catalogued as COSV54504056; called by muse, mutect2, varscan2
- CENPP | c.397T>A p.S133T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV65039612; called by muse, mutect2, varscan2
- CEP135 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57258744; called by muse, mutect2, varscan2
- CEP170 | c.2263del p.E755Rfs*62 | Frame Shift Del (DEL) | VAF 63/481 reads (13%) | catalogued as COSV60510266; called by mutect2, pindel, varscan2
- CFAP44 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 63/165 reads (38%) | catalogued as rs769673594, COSV55613144; called by muse, mutect2, varscan2
- CFAP92 | c.636C>A p.F212L | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54047989; called by muse, mutect2
- CFHR5 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 79/306 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56820729, COSV56823902; called by muse, mutect2, varscan2
- CGN | c.2064G>C p.K688N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV54971439; called by muse, mutect2, varscan2
- CHAMP1 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 191/338 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs201708961, COSV63522668; called by muse, mutect2, varscan2
- CHP2 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55650278; called by muse, mutect2, varscan2
- CHPT1 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV57533906; called by muse, mutect2
- CHRFAM7A | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100241737; called by mutect2, varscan2
- CHST5 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60340235; called by muse, mutect2, varscan2
- CHTF8 | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54707844; called by muse, mutect2
- CILP2 | c.1463T>A p.L488Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52277011; called by muse, mutect2, varscan2
- CLPB | c.894G>C p.M298I | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.178); catalogued as COSV53630998; called by muse, mutect2
- CNFN | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as COSV55772019; called by muse, mutect2, varscan2
- CNGB1 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.201); catalogued as COSV51903073; called by muse, mutect2, varscan2
- CNKSR2 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV54260398; called by muse, mutect2, varscan2
- CNTN1 | c.2378G>C p.G793A | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61641836; called by muse, mutect2, varscan2
- CNTN4 | c.2281G>T p.V761L | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV61871407, COSV61875748; called by muse, mutect2, varscan2
- COL11A1 | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62188436, COSV62202136; called by muse, mutect2, varscan2
- COL11A1 | c.1359G>T p.M453I | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV62188445, COSV62199669; called by muse, mutect2, varscan2
- COL12A1 | c.8257G>T p.G2753C | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59399853; called by muse, mutect2, varscan2
- COL15A1 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 14/117 reads (12%) | catalogued as COSV66646854; called by muse, mutect2, varscan2
- COL15A1 | c.4049C>T p.T1350M | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.287); catalogued as rs374842979; called by muse, mutect2, varscan2
- COL21A1 | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as COSV55169605, COSV99778542; called by muse, mutect2, varscan2
- COL22A1 | c.3176A>G p.K1059R | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.82); catalogued as rs1308579402, COSV57343415; called by muse, mutect2
- COL22A1 | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.084); catalogued as COSV57345019; called by muse, mutect2, varscan2
- COL24A1 | c.924G>C p.Q308H | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.172); catalogued as COSV65308986; called by muse, varscan2
- COL24A1 | c.388A>G p.R130G | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV65308990; called by muse, mutect2, varscan2
- COL4A1 | c.2842G>T p.G948C | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM130940, COSV65427944; called by muse, mutect2, varscan2
- COL4A1 | c.2841G>T p.K947N | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65427948; called by muse, mutect2, varscan2
- COL5A2 | c.361G>C p.V121L | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.147); catalogued as rs754180974, COSV66411265; called by muse, mutect2, varscan2
- COL6A6 | c.4108C>T p.R1370W | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs371511195; called by muse, mutect2, varscan2
- COLEC12 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 27/412 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.489); catalogued as COSV68371846; called by muse, mutect2
- COPA | c.2911C>G p.Q971E | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54105097; called by muse, mutect2, varscan2
- COPA | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54105116; called by muse, mutect2
- COPB1 | c.1792T>C p.S598P | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51449298; called by muse, mutect2, varscan2
- CPLANE2 | c.528-1G>C p.X176_splice | Splice Site (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100983294; called by muse, mutect2
- CPS1 | c.2546C>A p.T849K | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV51802670; called by muse, varscan2
- CPS1 | c.2724G>T p.K908N | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51815402; called by muse, mutect2, varscan2
- CPS1 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV51815415; called by muse, mutect2, varscan2
- CPXCR1 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52163256; called by muse, mutect2, varscan2
- CRB1 | c.2472C>G p.I824M | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV66331471, COSV66333925; called by muse, mutect2, varscan2
- CREG2 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV61317250; called by muse, mutect2, varscan2
- CRIP2 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV61274111, COSV61274444; called by muse, mutect2, varscan2
- CRLF3 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60836240; called by muse, mutect2, varscan2
- CRNN | c.522G>C p.Q174H | Missense Mutation (SNP) | VAF 148/728 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV55122730; called by muse, varscan2
- CROT | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58972920, COSV58974966; called by muse, mutect2
- CSMD1 | c.6757G>C p.A2253P (on ENST00000520002; = p.A2252P on NM_033225.6) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59344283; called by mutect2, varscan2
- CSMD1 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as COSV68224056; called by muse, mutect2
- CSMD2 | c.10117G>A p.G3373S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53928731; called by muse, mutect2, varscan2
- CSMD3 | c.9853C>A p.Q3285K (on ENST00000297405 / NM_001363185.1; = p.Q3116K on NM_052900.3) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV52229795, COSV52353222; called by muse, mutect2, varscan2
- CSMD3 | c.4087G>T p.G1363* (on ENST00000297405 / NM_001363185.1; = p.G1259* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 39/157 reads (25%) | catalogued as COSV52229810; called by muse, mutect2, varscan2
- CTLA4 | c.671G>T p.*224Lext*16 | Nonstop Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as COSV55592633; called by muse, mutect2, varscan2
- CTNNA2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.98); catalogued as COSV63564620; called by muse, varscan2
- CUL3 | c.963G>C p.L321F | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52366698; called by muse, mutect2, varscan2
- CUL9 | c.2035C>G p.Q679E | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV52730773; called by muse, mutect2
- CYFIP2 | c.1584T>A p.N528K | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as COSV59043733; called by muse, mutect2, varscan2
- CYLC1 | c.967A>G p.K323E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV61413505; called by muse, mutect2, varscan2
- DARS2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV53407704; called by muse, mutect2, varscan2
- DBI | c.28G>T p.A10S (on ENST00000355857 / NM_001079862.3; = p.A27S on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV58347298; called by muse, mutect2, varscan2
- DCBLD2 | c.1065G>C p.L355F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs1239054399, COSV58790962; called by muse, mutect2
- DCX | c.374A>T p.Y125F | Missense Mutation (SNP) | VAF 80/137 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV57567999, COSV57571630; called by muse, mutect2, varscan2
- DDX53 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as rs1569253298, COSV60069515; called by muse, mutect2
- DEAF1 | c.477G>C p.E159D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV58607911; called by muse, mutect2, varscan2
- DEFB110 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV100953754, COSV64484647; called by muse, mutect2
- DHX37 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.431); catalogued as rs552765231, COSV58136404; called by muse, mutect2, varscan2
- DICER1 | c.1671C>G p.I557M | Missense Mutation (SNP) | VAF 58/421 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV58623138; called by muse, mutect2, varscan2
- DISC1 | c.2448G>C p.Q816H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64103467, COSV64127008; called by muse, mutect2, varscan2
- DLGAP1 | c.2584C>T p.H862Y | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.925); catalogued as COSV59816175; called by muse, mutect2
- DLK1 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755998526, COSV57992425; called by muse, mutect2, varscan2
- DMBT1 | c.7255C>A p.H2419N (on ENST00000338354 / NM_001377530.1; = p.H1662N on NM_004406.3) | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV57547527, COSV57549855; called by muse, mutect2, varscan2
- DMXL1 | c.4262C>G p.S1421* | Nonsense Mutation (SNP) | VAF 47/256 reads (18%) | catalogued as COSV60715491; called by muse, mutect2, varscan2
- DMXL1 | c.5206G>C p.D1736H | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60715497; called by muse, mutect2, varscan2
- DNAH7 | c.11586+2T>G p.X3862_splice | Splice Site (SNP) | VAF 16/117 reads (14%) | catalogued as COSV56772603; called by muse, mutect2, varscan2
- DNAH8 | c.6421C>G p.L2141V | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766688342, COSV59460261; called by muse, mutect2, varscan2
- DNAH9 | c.2993G>C p.R998T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV52358655, COSV52376002; called by muse, mutect2, varscan2
- DNAH9 | c.5727C>A p.Y1909* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as COSV52358666; called by muse, mutect2, varscan2
- DNAJA4 | c.302G>C p.R101T (on ENST00000343789; = p.R130T on NM_018602.3) | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as COSV59426182; called by muse, mutect2, varscan2
- DNAJC13 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV53453574; called by muse, mutect2, varscan2
- DNAJC13 | c.6650C>T p.T2217I | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53453589; called by muse, mutect2
- DNMBP | c.2930A>G p.Y977C | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60628478; called by muse, mutect2, varscan2
- DOCK5 | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV52405477; called by muse, mutect2, varscan2
- DOCK6 | c.2884G>T p.G962* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV53917357; called by muse, mutect2, varscan2
- DOP1A | c.3832G>C p.E1278Q | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.193); catalogued as COSV52712811; called by muse, mutect2, varscan2
- DOP1B | c.2843G>T p.S948I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV67693498, COSV67694082; called by muse, mutect2, varscan2
- DPH2 | c.722G>T p.W241L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV52544033; called by muse, mutect2, varscan2
- DPH5 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1407633692, COSV59859822; called by muse, mutect2, varscan2
- DPPA4 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100169576, COSV59511410; called by muse, mutect2
- DPYSL3 | c.1698C>G p.I566M | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV58328303; called by muse, mutect2, varscan2
- DST | c.20446G>C p.E6816Q (on ENST00000361203 / NM_001374722.1; = p.E4513Q on NM_015548.5) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV55024217, COSV99759320; called by muse, varscan2
- DST | c.3052G>A p.D1018N (on ENST00000361203 / NM_001374722.1; = p.D692N on NM_001723.6) | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV55024232; called by muse, mutect2, varscan2
- DTNBP1 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV59038871; called by muse, mutect2, varscan2
- EBLN2 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.988); catalogued as COSV55596603; called by muse, mutect2
- EDEM3 | c.900G>T p.L300F | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); catalogued as COSV58925787; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 128/359 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs754312859, COSV62567475; called by muse, mutect2, varscan2
- EFCAB13 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV58945696, COSV58950054; called by muse, mutect2, varscan2
- EGFR | c.629-2A>G p.X210_splice | Splice Site (SNP) | VAF 68/1668 reads (4%) | catalogued as COSV51817116; called by muse, mutect2
- EIF2S2 | c.954C>A p.F318L | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV66621848; called by muse, mutect2, varscan2
- EIF4G1 | c.2560G>C p.D854H (on ENST00000346169 / NM_198241.3; = p.D659H on NM_004953.5) | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59992104; called by muse, mutect2
- EIF4G3 | c.1462C>G p.Q488E | Missense Mutation (SNP) | VAF 60/446 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as COSV51675375; called by muse, mutect2, varscan2
- EIPR1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 90/376 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs376448610; called by muse, mutect2, varscan2
- ELF4 | c.594G>C p.R198S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV57453475; called by muse, mutect2, varscan2
- ELL2 | c.1710C>G p.I570M | Missense Mutation (SNP) | VAF 33/516 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as COSV52983618; called by muse, mutect2
- ENDOD1 | c.1420C>G p.L474V | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53590052; called by muse, mutect2, varscan2
- EPB41L2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61356955; called by muse, varscan2
- EPB41L3 | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 64/517 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1012123253, COSV59459326; called by muse, mutect2, varscan2
- EPHA5 | c.2526C>G p.I842M | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56654517; called by muse, mutect2, varscan2
- EPHA6 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as rs763378493, COSV67579596; called by muse, mutect2, varscan2
- EPN1 | c.1538G>T p.G513V (on ENST00000270460 / NM_001321263.1; = p.G487V on NM_013333.3) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV50039749; called by muse, mutect2, varscan2
- EPN2 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59062044; called by muse, mutect2
- EPS8 | c.1919C>G p.S640C | Missense Mutation (SNP) | VAF 128/315 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV55533107; called by muse, mutect2, varscan2
- ERICH3 | c.4138G>A p.D1380N | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as COSV58611038; called by muse, mutect2, varscan2
- ESAM | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV54035729; called by muse, mutect2, varscan2
- ESYT1 | c.1534C>G p.Q512E | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as COSV57274579; called by muse, mutect2, varscan2
- EVX2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57962662; called by muse, mutect2, varscan2
- EXOC1 | c.1148G>C p.R383T | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV62120951, COSV62120981; called by muse, mutect2, varscan2
- EXOC4 | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV54106390; called by muse, mutect2, varscan2
- F11 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 133/349 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53002396; called by muse, mutect2, varscan2
- FAM114A1 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1220553530, COSV62673537; called by muse, mutect2, varscan2
- FAM114A2 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV61078263; called by muse, mutect2, varscan2
- FAM135B | c.2367G>T p.K789N | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as COSV52736169; called by muse, mutect2, varscan2
- FAM135B | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 18/301 reads (6%) | catalogued as COSV52725585; called by muse, mutect2
- FAM162A | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as COSV51658747; called by muse, mutect2, varscan2
- FAM216B | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV58270891; called by muse, mutect2, varscan2
- FAM91A1 | c.1958G>A p.C653Y | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58238025; called by muse, mutect2
- FAM98C | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.819); catalogued as COSV53039236, COSV53040103; called by muse, mutect2, varscan2
- FASN | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60757287; called by muse, mutect2, varscan2
- FAT4 | c.9047G>T p.G3016V | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58694235; called by muse, mutect2, varscan2
- FAXDC2 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV58172979; called by muse, mutect2, varscan2
- FBN3 | c.7034C>T p.S2345F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV54465072; called by muse, mutect2, varscan2
- FBXO11 | c.1093G>A p.E365K (on ENST00000403359 / NM_001190274.2; = p.E281K on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/381 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV57022061; called by muse, mutect2, varscan2
- FBXO25 | c.507C>G p.I169M (on ENST00000382824 / NM_183421.2; = p.I102M on NM_012173.3) | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52337711; called by muse, mutect2, varscan2
- FBXO27 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 242/491 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.188); catalogued as COSV53072693; called by muse, varscan2
- FBXW7 | c.2033C>G p.S678* (on ENST00000281708 / NM_001349798.2; = p.S598* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 50/309 reads (16%) | catalogued as COSV55897853; called by muse, mutect2, varscan2
- FCAR | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs867266528, COSV62029972, COSV62030183; called by mutect2, varscan2
- FCRL3 | c.2171A>T p.N724I | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63843046, COSV63845196; called by muse, mutect2, varscan2
- FDXACB1 | c.1351C>A p.R451S | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52786727, COSV52789352; called by muse, mutect2, varscan2
- FER1L6 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.058); catalogued as COSV67551190; called by muse, mutect2, varscan2
- FITM1 | c.489C>G p.H163Q | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.511); catalogued as COSV52824754; called by muse, mutect2, varscan2
- FLG | c.1933C>G p.H645D | Missense Mutation (SNP) | VAF 289/814 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV64244016; called by muse, mutect2, varscan2
- FLT1 | c.1337T>A p.L446Q | Missense Mutation (SNP) | VAF 95/184 reads (52%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.832); catalogued as COSV56732848; called by muse, mutect2, varscan2
- FOS | c.824C>A p.P275Q | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV57839842; called by muse, mutect2, varscan2
- FOXD2 | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100599331; called by muse, mutect2, varscan2
- FOXF1 | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV52287250; called by muse, mutect2
- FRAS1 | c.917G>A p.C306Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168727642, COSV53624389; called by muse, mutect2, varscan2
- FRMD3 | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV58464246; called by muse, mutect2
- FRMPD2 | c.2031G>C p.Q677H | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV100563399, COSV59719832; called by muse, mutect2, varscan2
- FRY | c.4648G>A p.E1550K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.281); catalogued as COSV66573315; called by muse, mutect2, varscan2
- FRYL | c.4069G>C p.G1357R | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51952221, COSV99977118; called by muse, mutect2, varscan2
- FSCB | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61218690; called by muse, mutect2
- FUBP1 | c.1576+1del p.X526_splice | Splice Site (DEL) | VAF 14/87 reads (16%) | catalogued as COSV53930058; called by mutect2, pindel, varscan2
- G2E3 | c.890A>T p.K297I | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV52841326; called by muse, mutect2, varscan2
- GABRA1 | c.313A>T p.K105* | Nonsense Mutation (SNP) | VAF 55/289 reads (19%) | catalogued as COSV50109648; called by muse, mutect2, varscan2
- GABRA2 | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV62916465, COSV62916815; called by muse, mutect2, varscan2
- GABRD | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as rs764066786, COSV66081187; called by muse, mutect2, varscan2
- GADD45G | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV53000163; called by muse, mutect2, varscan2
- GALNT12 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV66662315, COSV66663283; called by muse, mutect2, varscan2
- GALNT18 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57152247; called by muse, mutect2, varscan2
- GARNL3 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.472); catalogued as COSV59228006; called by muse, mutect2, varscan2
- GCN1 | c.6163G>A p.E2055K | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs751679365, COSV56110335; called by muse, mutect2, varscan2
- GCNT3 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as COSV68531961, COSV68532273; called by muse, mutect2, varscan2
- GCSAM | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58263806; called by muse, mutect2
- GIT1 | c.2165C>A p.P722Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV56403083; called by muse, mutect2
- GLB1L | c.1290C>G p.F430L | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55477347; called by muse, mutect2, varscan2
- GLRB | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52418823, COSV52419681; called by muse, mutect2, varscan2
- GLT1D1 | c.985G>T p.E329* (on ENST00000442111 / NM_001366889.1; = p.E249* on NM_144669.3) | Nonsense Mutation (SNP) | VAF 38/198 reads (19%) | catalogued as COSV55883947; called by muse, varscan2
- GLYATL1 | c.472C>A p.P158T (on ENST00000317391 / NM_001354699.1; = p.P189T on NM_080661.4) | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs766739429, COSV55609837; called by muse, mutect2, varscan2
- GNA12 | c.784A>C p.M262L | Missense Mutation (SNP) | VAF 94/366 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV51742735; called by muse, mutect2, varscan2
- GNPTAB | c.2044G>T p.D682Y | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV68449756; called by muse, mutect2, varscan2
- GPANK1 | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV63263914; called by muse, mutect2, varscan2
- GPC5 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65609541; called by muse, mutect2, varscan2
- GPR1 | c.286T>G p.Y96D | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67977095; called by muse, mutect2, varscan2
- GPR156 | c.1587G>C p.E529D | Missense Mutation (SNP) | VAF 99/434 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV59940951; called by muse, mutect2, varscan2
- GPR18 | c.945C>G p.F315L | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs762415931, COSV61621329; called by muse, mutect2, varscan2
- GPR45 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 138/446 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51524784; called by muse, mutect2, varscan2
- GPR61 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV68177806; called by muse, mutect2, varscan2
- GPRIN3 | c.2203A>G p.I735V | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs749356839, COSV60885433; called by muse, mutect2, varscan2
- GRAMD1C | c.89C>G p.P30R | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.209); catalogued as COSV63983185; called by muse, mutect2
- GREM2 | c.304A>C p.N102H | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58953169; called by muse, mutect2, varscan2
- GRID2 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56225657; called by muse, mutect2, varscan2
- GRIK1 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV58723612; called by muse, mutect2, varscan2
- GRM5 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 15/369 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV59599864; called by muse, mutect2
- GSN | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV57998823, COSV58001210; called by muse, mutect2, varscan2
- H2AC20 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58612490, COSV58612937; called by muse, mutect2, varscan2
- H2AX | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV53829085; called by muse, mutect2, varscan2
- H3C7 | c.237C>G p.F79L | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.349); catalogued as COSV55100302; called by muse, mutect2, varscan2
- HECA | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV62769872; called by muse, mutect2, varscan2
- HERC2 | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV55332740; called by muse, mutect2, varscan2
- HGD | c.1320C>A p.N440K | Missense Mutation (SNP) | VAF 58/407 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52199373; called by muse, mutect2, varscan2
- HIC2 | c.27-1G>A p.X9_splice | Splice Site (SNP) | VAF 12/78 reads (15%) | catalogued as COSV68042480; called by muse, varscan2
- HIVEP2 | c.3400G>T p.D1134Y | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV50021994; called by muse, mutect2, varscan2
- HIVEP3 | c.2726G>A p.R909H | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56018158; called by muse, mutect2, varscan2
- HLA-A | c.896-1G>C p.X299_splice | Splice Site (SNP) | VAF 32/113 reads (28%) | catalogued as COSV65139440; called by muse, mutect2, varscan2
- HLTF | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 36/504 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV59501934; called by muse, mutect2
- HMCN1 | c.15905G>C p.R5302T | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV54914582; called by muse, mutect2, varscan2
- HOOK1 | c.1695G>C p.Q565H | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV64619001, COSV64619605; called by muse, mutect2, varscan2
- HOXC6 | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54537442; called by muse, mutect2, varscan2
- HRG | c.1262C>G p.P421R | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV51645578, COSV51646419; called by muse, mutect2
- HSPA9 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51865163; called by muse, mutect2
- HUWE1 | c.8177C>G p.S2726* | Nonsense Mutation (SNP) | VAF 10/101 reads (10%) | catalogued as COSV53352970; called by muse, mutect2, varscan2
- IFNB1 | c.414G>C p.M138I | Missense Mutation (SNP) | VAF 53/401 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.448); catalogued as COSV66525548; called by muse, mutect2, varscan2
- IGHMBP2 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 61/103 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV54823811; called by muse, mutect2, varscan2
- IGSF5 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 19/126 reads (15%) | catalogued as rs748941524, COSV66029335; called by muse, mutect2, varscan2
- IGSF8 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.462); catalogued as rs144014563; called by muse, mutect2, varscan2
- IL13RA1 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.865); catalogued as COSV100861553, COSV65424700; called by muse, mutect2, varscan2
- IL17RE | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV55969301, COSV55970617; called by muse, mutect2, varscan2
- ILRUN | c.754C>T p.P252S (on ENST00000374023 / NM_024294.4; = p.P186S on NM_022758.6) | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.085); catalogued as COSV64990577; called by muse, mutect2, varscan2
- IMPA1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56272005; called by muse, mutect2
- INPP4B | c.2637G>A p.M879I | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764114435, COSV53732336; called by muse, mutect2, varscan2
- INPP4B | c.2329C>G p.L777V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV53732360; called by muse, mutect2
- INTS3 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59679195; called by muse, mutect2, varscan2
- ITGAX | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV51647790; called by muse, mutect2, varscan2
- JMJD1C | c.3995G>C p.R1332T | Missense Mutation (SNP) | VAF 98/373 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV59516455; called by muse, mutect2, varscan2
- KALRN | c.5041G>T p.E1681* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV62567133, COSV62571404; called by muse, mutect2, varscan2
- KBTBD6 | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65271578; called by muse, mutect2
- KCTD7 | c.718C>T p.R240W (on ENST00000275532; = p.S253L on NM_153033.5) | Missense Mutation (SNP) | VAF 21/260 reads (8%) | PolyPhen benign (0.001); catalogued as rs761940050, COSV51877022; called by muse, mutect2
- KDM5B | c.3971C>T p.S1324L | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV52509624; called by muse, mutect2, varscan2
- KDM5B | c.3799C>T p.Q1267* | Nonsense Mutation (SNP) | VAF 77/236 reads (33%) | catalogued as rs1270198556, COSV52509637; called by muse, mutect2, varscan2
- KDM5B | c.3409G>C p.E1137Q | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV52509660; called by muse, varscan2
- KDM5B | c.3045G>C p.Q1015H | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV52507506, COSV52509673; called by muse, varscan2
- KDM5B | c.2232G>A p.M744I | Missense Mutation (SNP) | VAF 130/448 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs1343902808, COSV52509682; called by muse, mutect2, varscan2
- KDM5B | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs1264779837, COSV52509690; called by muse, varscan2
- KDM8 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53730423; called by muse, mutect2, varscan2
- KIAA0586 | c.70G>A p.E24K (on ENST00000619416 / NM_001244190.2; = p.E39K on NM_014749.5) | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53621876; called by muse, mutect2
- KIAA1958 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61725200; called by muse, mutect2, varscan2
- KIAA1958 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.824); catalogued as COSV61725211; called by muse, mutect2, varscan2
- KIF21A | c.2497C>G p.L833V (on ENST00000361418 / NM_001378440.1; = p.L820V on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs979633626, COSV62767266, COSV62777812; called by muse, varscan2
- KIF4B | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 213/399 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV70528391, COSV70530194; called by muse, mutect2, varscan2
- KIF5C | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV69172288; called by muse, mutect2, varscan2
- KIRREL1 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1469320581, COSV63287220; called by muse, mutect2
- KLHL4 | c.1422T>G p.I474M | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.857); catalogued as COSV64144332; called by muse, mutect2, varscan2
- KMT2C | c.3281A>G p.Y1094C | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51460004; called by muse, mutect2, varscan2
- KMT2D | c.4130A>G p.Q1377R | Missense Mutation (SNP) | VAF 193/511 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56458012, COSV56488509; called by muse, mutect2, varscan2
- KMT2E | c.4508C>T p.A1503V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV57576070; called by muse, mutect2, varscan2
- KNG1 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 28/301 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53979057; called by muse, mutect2
- KNG1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs779764784, COSV53979073, COSV53979592; called by muse, mutect2, varscan2
- KNTC1 | c.1344G>C p.Q448H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV61079406; called by muse, mutect2, varscan2
- KRBA1 | c.465C>T p.I155= | Splice Region (SNP) | VAF 7/30 reads (23%) | catalogued as COSV55442520; called by muse, mutect2, varscan2
- KRT12 | c.374A>T p.E125V | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52431480; called by muse, mutect2
- KRT28 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs769997190, COSV60685630; called by muse, mutect2
- KRTAP10-5 | c.593C>A p.S198* | Nonsense Mutation (SNP) | VAF 72/368 reads (20%) | catalogued as COSV59954524, COSV59968821; called by muse, mutect2, varscan2
- KY | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV71017914; called by muse, mutect2, varscan2
- LAMA1 | c.6206G>C p.R2069T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.14); catalogued as COSV101055576, COSV67539611; called by muse, mutect2, varscan2
- LAMA1 | c.1617C>G p.I539M | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1306260317, COSV67539615; called by muse, mutect2, varscan2
- LAMC1 | c.4212G>C p.K1404N | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV51151217; called by muse, mutect2, varscan2
- LARGE1 | c.1351T>C p.F451L | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61665335; called by muse, mutect2, varscan2
- LDAH | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 33/764 reads (4%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as COSV52971561; called by muse, mutect2
- LDHC | c.451A>G p.S151G | Missense Mutation (SNP) | VAF 106/267 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55004835; called by muse, mutect2, varscan2
- LDLRAD4 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.969); catalogued as rs748709104, COSV63339590; called by muse, varscan2
- LMBRD2 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV56951086; called by muse, mutect2, varscan2
- LMNTD1 | c.563del p.S188Ffs*10 | Frame Shift Del (DEL) | VAF 77/415 reads (19%) | catalogued as COSV51445447; called by mutect2, pindel, varscan2
- LMX1B | c.667C>G p.R223G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as CM091610, CM104374, COSV62738554, COSV62740613; called by muse, mutect2, varscan2
- LPIN2 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55241315; called by muse, mutect2
- LRFN5 | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53264242; called by muse, mutect2, varscan2
- LRP3 | c.290A>T p.H97L | Missense Mutation (SNP) | VAF 136/280 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.248); catalogued as COSV53505222; called by muse, varscan2
- LRP4 | c.1533G>C p.E511D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as COSV66136850; called by muse, mutect2
- LRRC29 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV58527641; called by muse, mutect2, varscan2
- LRRC32 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs748881614, COSV52633859; called by muse, mutect2, varscan2
- LRRC49 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV51436786, COSV51437243; called by muse, mutect2, varscan2
- LRRC66 | c.1374C>G p.F458L | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV58632876, COSV58635285; called by muse, mutect2, varscan2
- LRRFIP1 | c.1918G>A p.E640K (on ENST00000392000 / NM_001137552.2; = p.E616K on NM_004735.4) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV55253435; called by muse, mutect2, varscan2
- LTBP4 | c.3013G>A p.D1005N (on ENST00000308370 / NM_001042544.1; = p.D968N on NM_003573.2) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52584899; called by muse, mutect2
- LYST | c.5039C>G p.S1680* | Nonsense Mutation (SNP) | VAF 26/97 reads (27%) | catalogued as COSV67709403; called by muse, mutect2, varscan2
- LZTS3 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV61278340; called by muse, mutect2, varscan2
- MACROD1 | c.410T>A p.V137E | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55363090; called by muse, mutect2
- MACROD2 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV54009198, COSV54011633; called by muse, mutect2, varscan2
- MAGEA6 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 104/180 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs782213540, COSV61449170; called by muse, mutect2
- MAGEA6 | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 101/174 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV61449165; called by muse, mutect2
- MAGED1 | c.2162G>C p.G721A | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.981); catalogued as COSV58515848; called by muse, mutect2, varscan2
- MAPKAPK5 | c.635C>A p.S212* | Nonsense Mutation (SNP) | VAF 37/118 reads (31%) | catalogued as COSV72431641; called by muse, mutect2, varscan2
- MARVELD3 | c.1006G>T p.V336L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.853); catalogued as COSV51705128; called by muse, mutect2
- MATN4 | c.1433C>T p.S478F (on ENST00000372754; = p.S437F on NM_003833.4) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | PolyPhen probably damaging (0.982); catalogued as COSV61351880; called by muse, mutect2, varscan2
- MAZ | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50716363; called by muse, mutect2, varscan2
- MBD4 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV51445056; called by muse, mutect2
- MBLAC1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs768084664, COSV53542825, COSV53542932; called by muse, mutect2, varscan2
- MCC | c.305G>C p.R102P | Missense Mutation (SNP) | VAF 49/297 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.24); catalogued as COSV68727485, COSV68728447; called by muse, mutect2, varscan2
- MCF2L2 | c.1595G>C p.R532P | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61048520; called by muse, mutect2
- MCOLN3 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV62014920; called by muse, mutect2, varscan2
- MDP1 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 36/870 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV51660992; called by muse, mutect2
- ME2 | c.1623C>G p.F541L | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1181168227, COSV58423938; called by muse, mutect2
- MECOM | c.163G>A p.E55K (on ENST00000468789 / NM_001105078.4; = p.E243K on NM_004991.4) | Missense Mutation (SNP) | VAF 142/739 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.024); catalogued as rs1002948185, COSV52958465, COSV52964959; called by muse, mutect2, varscan2
- MED13L | c.6032A>T p.N2011I | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV56123752; called by muse, mutect2
- MEP1A | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 78/216 reads (36%) | catalogued as COSV57921183; called by muse, mutect2, varscan2
- MGAM | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.224); catalogued as COSV72075008; called by muse, mutect2, varscan2
- MIA3 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV60514695; called by muse, mutect2, varscan2
- MIEF2 | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV59902118; called by muse, mutect2
- MINAR1 | c.1495A>C p.S499R | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV59584313; called by muse, mutect2, varscan2
- MINDY4 | c.1481G>A p.C494Y | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54675677; called by muse, mutect2
- MIS18A | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.153); catalogued as COSV51589578; called by muse, mutect2, varscan2
- MMP19 | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59452046; called by muse, mutect2, varscan2
- MMS19 | c.920G>C p.R307T | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV59136182; called by muse, mutect2
- MOGS | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 20/550 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV51970387; called by muse, mutect2
- MON2 | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.455); catalogued as COSV54809940; called by muse, mutect2, varscan2
- MPP4 | c.1195G>T p.V399L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1351723521, COSV59632401; called by muse, mutect2, varscan2
- MROH1 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV58187590; called by muse, mutect2, varscan2
- MRPL37 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60322087; called by muse, mutect2, varscan2
- MRPL46 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV56900315; called by muse, varscan2
- MSH5 | c.249G>C p.E83D | Missense Mutation (SNP) | VAF 107/303 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV65210284; called by muse, mutect2, varscan2
- MTHFD1 | c.1891C>G p.P631A | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53701680; called by muse, mutect2, varscan2
- MTNR1B | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 120/462 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1201633065, COSV57067279; called by muse, mutect2, varscan2
- MUC3A | c.9231G>A p.L3077= | Splice Region (SNP) | VAF 14/110 reads (13%) | catalogued as COSV60219221; called by muse, mutect2
- MUC4 | c.14465C>A p.S4822Y (on ENST00000463781 / NM_018406.7; = p.S586Y on NM_004532.6) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.694); catalogued as rs1478821650, COSV57789381; called by muse, mutect2
- MYBBP1A | c.2968A>T p.N990Y | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54593995, COSV54599737; called by muse, mutect2, varscan2
- MYCBP2 | c.4459C>T p.Q1487* (on ENST00000357337; = p.Q1525* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 22/356 reads (6%) | catalogued as COSV62027269; called by muse, mutect2
- MYF5 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57355600, COSV99953472; called by muse, mutect2, varscan2
- MYH15 | c.2310T>A p.F770L | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV56313768; called by muse, mutect2, varscan2
- MYH2 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV55441754; called by muse, mutect2, varscan2
- MYH8 | c.5658G>T p.E1886D | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV67967876; called by muse, mutect2
- MYH8 | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 176/497 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as COSV67967884; called by muse, mutect2, varscan2
- MYLK | c.2430G>T p.M810I | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as COSV60614302; called by muse, mutect2, varscan2
- MYO10 | c.1870G>T p.A624S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.289); catalogued as COSV72563231; called by muse, mutect2, varscan2
- MYO1E | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55690286; called by muse, mutect2, varscan2
- MYOM1 | c.4140G>T p.V1380= | Splice Region (SNP) | VAF 15/296 reads (5%) | catalogued as COSV55295070; called by muse, mutect2
- MYPN | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV62735373; called by muse, mutect2, varscan2
- NAA11 | c.409T>C p.Y137H | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1433253231, COSV54514956; called by muse, mutect2, varscan2
- NARS2 | c.1104T>G p.N368K | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV55253261; called by muse, mutect2
- NCAM2 | c.1918C>G p.L640V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as COSV53085764; called by muse, varscan2
- NCAM2 | c.1960G>T p.E654* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV53072144, COSV53105366; called by muse, varscan2
- NCBP1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV64317016; called by muse, mutect2
- NCBP3 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50108622; called by muse, mutect2, varscan2
- NCKAP1L | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 62/703 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV53208945; called by muse, mutect2
- NCR1 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52557350, COSV99401054; called by muse, mutect2, varscan2
- NDNF | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV65633382; called by muse, mutect2, varscan2
- NDST3 | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV56622642; called by muse, mutect2
- NEB | c.11965G>A p.D3989N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50836356; called by muse, mutect2, varscan2
- NES | c.2125G>C p.E709Q | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV63961601; called by muse, mutect2
- NES | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV63961609; called by muse, mutect2
- NF1 | c.4441G>C p.D1481H (on ENST00000358273 / NM_001042492.3; = p.D1460H on NM_000267.3) | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV62209183; called by muse, mutect2
- NFKBIL1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1259494445, COSV65990586; called by muse, mutect2, varscan2
- NLRP14 | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as COSV55068996; called by muse, mutect2, varscan2
- NLRP3 | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.722); catalogued as COSV60227428; called by muse, mutect2
- NLRP7 | c.2186G>T p.G729V (on ENST00000340844 / NM_206828.3; = p.G701V on NM_139176.3) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV60176901; called by muse, mutect2, varscan2
- NME7 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV63168343; called by muse, mutect2
- NME7 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 160/283 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs139755731; called by muse, mutect2, varscan2
- NMI | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | catalogued as COSV54638509; called by muse, mutect2
- NOC4L | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs367698251; called by muse, mutect2, varscan2
- NODAL | c.297C>G p.S99R | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV54661861; called by muse, mutect2, varscan2
- NOS1 | c.2979C>A p.H993Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV57615743; called by muse, varscan2
- NOTCH3 | c.1732C>G p.R578G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.972); catalogued as CM961047, COSV54639394, COSV54646154, COSV54650741; called by muse, mutect2, varscan2
- NPHP3 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 56/346 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV58631419; called by muse, mutect2, varscan2
- NR1H4 | c.402T>A p.D134E (on ENST00000551379 / NM_001206993.2; = p.D124E on NM_005123.4) | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51853825; called by muse, mutect2, varscan2
- NR1H4 | c.530del p.G177Afs*4 (on ENST00000551379 / NM_001206993.2; = p.G167Afs*4 on NM_005123.4) | Frame Shift Del (DEL) | VAF 26/137 reads (19%) | catalogued as rs1566461780; called by mutect2, pindel, varscan2
- NSUN6 | c.1325C>A p.A442D | Missense Mutation (SNP) | VAF 56/492 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56627463, COSV56634101; called by muse, mutect2, varscan2
- NT5DC1 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV60309931; called by muse, mutect2, varscan2
- NTAQ1 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs909797192, COSV54875182; called by muse, mutect2, varscan2
- NUP155 | c.3947G>C p.R1316T (on ENST00000231498 / NM_153485.3; = p.R1257T on NM_004298.4) | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV51531671; called by muse, mutect2, varscan2
- NUTM1 | c.1315C>G p.L439V | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as COSV59217625; called by muse, mutect2, varscan2
- NWD1 | c.4130C>A p.A1377E | Missense Mutation (SNP) | VAF 44/372 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV60345499; called by muse, mutect2, varscan2
- OLFML2B | c.1331T>C p.M444T | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54197766; called by muse, mutect2, varscan2
- OPN5 | c.999-2A>G p.X333_splice | Splice Site (SNP) | VAF 47/141 reads (33%) | catalogued as COSV55246273; called by muse, mutect2, varscan2
- OR10X1 | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.48); catalogued as COSV63767577; called by muse, mutect2
- OR11H1 | c.650T>A p.F217Y | Missense Mutation (SNP) | VAF 36/363 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.219); catalogued as COSV53272166; called by muse, mutect2, varscan2
- OR13D1 | c.52C>A p.H18N | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); catalogued as COSV59514221; called by muse, mutect2, varscan2
- OR1B1 | c.480G>T p.L160F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV59171967; called by muse, mutect2, varscan2
- OR2G6 | c.529A>T p.I177F | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58575039; called by muse, mutect2, varscan2
- OR2T29 | c.50T>G p.I17S | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV60771641; called by muse, mutect2, varscan2
- OR4A15 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 84/399 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV59036112; called by muse, mutect2, varscan2
- OR51M1 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 115/295 reads (39%) | catalogued as COSV60784899; called by muse, mutect2, varscan2
- OR52E4 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV57625336; called by muse, mutect2, varscan2
- OR5H15 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62948504, COSV62948786; called by muse, mutect2, varscan2
- OR5I1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1205164658, COSV56886384, COSV56887803; called by muse, mutect2, varscan2
- OR5J2 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); catalogued as COSV56620763, COSV56622138; called by muse, mutect2, varscan2
- OR5K2 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 55/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV71143292; called by muse, mutect2, varscan2
- OR5M11 | c.433A>T p.T145S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV73141917; called by muse, varscan2
- OR5M11 | c.376T>A p.Y126N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV73141918; called by muse, varscan2
- OR5T3 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 154/647 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs987291844, COSV100282946, COSV57381541; called by muse, mutect2, varscan2
- OR5W2 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60616895; called by muse, mutect2, varscan2
- OR6F1 | c.868T>A p.Y290N | Missense Mutation (SNP) | VAF 76/263 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57468416; called by muse, mutect2, varscan2
- OR6K2 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.941); catalogued as COSV62743745; called by muse, mutect2, varscan2
- OR6N1 | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.755); catalogued as rs1468988450, COSV58649270, COSV58650226; called by muse, mutect2
- OR7C2 | c.802A>G p.R268G | Missense Mutation (SNP) | VAF 96/245 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV50181099; called by muse, mutect2, varscan2
- ORC1 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 86/325 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV65364398; called by muse, mutect2, varscan2
- OSBPL2 | c.963del p.R322Gfs*6 (on ENST00000313733 / NM_144498.4; = p.R310Gfs*6 on NM_014835.4) | Frame Shift Del (DEL) | VAF 21/144 reads (15%) | catalogued as COSV58216194; called by mutect2, pindel, varscan2
- P2RY4 | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); catalogued as COSV100997065, COSV65736844; called by muse, mutect2, varscan2
- P2RY4 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs770348089, COSV65736764; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.524A>T p.K175M (on ENST00000259318 / NM_001136562.3; = p.K406M on NM_007203.5) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52178497; called by muse, mutect2, varscan2
- PAN3 | c.1630C>G p.Q544E | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.546); catalogued as rs1364587052, COSV56704773; called by muse, mutect2
- PAPPA2 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62781095; called by muse, mutect2
- PARS2 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV64883718; called by muse, mutect2, varscan2
- PBRM1 | c.2467G>C p.D823H | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV56285767; called by muse, mutect2, varscan2
- PCDH15 | c.3466G>A p.D1156N | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as CM1515076, COSV57342165; called by muse, mutect2, varscan2
- PCDH15 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 26/183 reads (14%) | catalogued as COSV57335661; called by muse, mutect2, varscan2
- PCDHA12 | c.976G>C p.G326R | Missense Mutation (SNP) | VAF 109/206 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56520025; called by muse, mutect2, varscan2
- PCDHGA8 | c.2065C>T p.L689F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53978714; called by muse, mutect2, varscan2
- PCDHGB7 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as COSV53978726; called by muse, mutect2, varscan2
- PCDHGB7 | c.2294T>G p.F765C | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV53978738, COSV99542467; called by muse, mutect2, varscan2
- PCNT | c.9840-1G>C p.X3280_splice | Splice Site (SNP) | VAF 13/153 reads (8%) | catalogued as COSV64030109; called by muse, mutect2
- PCNX1 | c.3643C>T p.Q1215* | Nonsense Mutation (SNP) | VAF 60/198 reads (30%) | catalogued as COSV53097156; called by muse, mutect2, varscan2
- PDE2A | c.2328C>G p.I776M | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57809623; called by muse, mutect2
- PDILT | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV56702961; called by muse, mutect2, varscan2
- PEX5L | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 44/441 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV55849619; called by muse, mutect2, varscan2
- PFDN5 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV54476384; called by muse, mutect2, varscan2
- PHACTR4 | c.1960C>G p.Q654E (on ENST00000373839 / NM_001350159.2; = p.Q664E on NM_023923.4) | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as COSV65784471; called by muse, mutect2, varscan2
- PHAX | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV52551612; called by muse, mutect2, varscan2
- PHF3 | c.2249G>T p.S750I | Missense Mutation (SNP) | VAF 66/556 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50324738; called by muse, varscan2
- PHF3 | c.2848G>T p.V950L | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV50324763; called by muse, mutect2
- PHLDB2 | c.388C>G p.H130D | Missense Mutation (SNP) | VAF 68/612 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); catalogued as COSV67313211; called by muse, mutect2, varscan2
- PIBF1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1442175728, COSV58325073; called by muse, mutect2, varscan2
- PIH1D2 | c.250C>G p.H84D | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV54775847; called by muse, mutect2
- PIK3CG | c.2121A>T p.R707S | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63250077; called by muse, mutect2, varscan2
- PIK3R4 | c.2239A>T p.M747L | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63242005; called by muse, mutect2, varscan2
- PKD1L1 | c.8015T>G p.L2672R | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV51843404; called by muse, mutect2, varscan2
- PKDREJ | c.4807G>A p.G1603S | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.617); catalogued as rs546954517, COSV53550541; called by muse, mutect2, varscan2
- PKHD1 | c.2059C>G p.Q687E | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV61883804; called by muse, mutect2, varscan2
- PKHD1L1 | c.1942C>A p.P648T | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs777191851, COSV65746729; called by muse, mutect2, varscan2
- PKNOX1 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV52337406; called by muse, mutect2, varscan2
- PKNOX1 | c.1269C>G p.H423Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV52337424; called by muse, mutect2, varscan2
- PKP2 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 15/381 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV50735543; called by muse, mutect2
- PLA2G7 | c.677C>A p.A226E | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51262368; called by muse, mutect2, varscan2
- PLAAT2 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as COSV55375126; called by muse, mutect2
- PLAGL2 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 10/336 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs955173582, COSV55788865; called by muse, mutect2
- PLB1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV59829510; called by muse, mutect2, varscan2
- PLCB1 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62041673, COSV62055698, COSV62058096; called by muse, mutect2
- PLCXD3 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60611922; called by mutect2, varscan2
- PLCZ1 | c.928A>T p.R310* | Nonsense Mutation (SNP) | VAF 53/90 reads (59%) | catalogued as COSV56855378; called by muse, mutect2, varscan2
- PLD1 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as COSV60570111; called by muse, mutect2, varscan2
- PLD1 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 30/582 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV60570120; called by muse, mutect2
- PLEKHG1 | c.3641C>G p.S1214* | Nonsense Mutation (SNP) | VAF 16/296 reads (5%) | catalogued as COSV62048739; called by muse, mutect2
- PLEKHG2 | c.3194A>T p.Q1065L | Missense Mutation (SNP) | VAF 52/376 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV52686114; called by muse, mutect2, varscan2
- PLEKHG4B | c.3577G>C p.D1193H (on ENST00000283426; = p.D1549H on NM_052909.5) | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV52050244; called by muse, mutect2
- PLEKHM1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as COSV69599158; called by muse, mutect2, varscan2
- PLEKHM1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV69599160; called by muse, varscan2
- PLEKHM1 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV69599162; called by muse, varscan2
- PLEKHM2 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV53817580; called by muse, varscan2
- PLK3 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59500276; called by muse, mutect2, varscan2
- PLXNC1 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.625); catalogued as COSV51577031, COSV51578193, COSV99312649; called by muse, mutect2, varscan2
- PLXNC1 | c.1229C>G p.S410* | Nonsense Mutation (SNP) | VAF 26/228 reads (11%) | catalogued as rs752253626, COSV51576415, COSV51578205; called by muse, mutect2, varscan2
- PMFBP1 | c.2593G>T p.D865Y (on ENST00000537465; = p.D860Y on NM_031293.3) | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52820613, COSV52826991; called by muse, mutect2, varscan2
- POC5 | c.942G>C p.Q314H (on ENST00000428202 / NM_001099271.2; = p.Q289H on NM_152408.2) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV62807605; called by muse, mutect2, varscan2
- POM121 | c.3693G>C p.K1231N (on ENST00000434423; = p.K966N on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57518998, COSV99988539; called by muse, mutect2, varscan2
- POM121C | c.1122G>C p.L374F (on ENST00000607367; = p.L132F on NM_001099415.3) | Missense Mutation (SNP) | VAF 72/582 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV57547224; called by muse, mutect2, varscan2
- POR | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67517509; called by muse, mutect2, varscan2
- POTEH | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs777074196, COSV100625312; called by muse, mutect2, varscan2
- PPIP5K2 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV58607056; called by muse, mutect2, varscan2
- PPIP5K2 | c.3175C>T p.H1059Y | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as COSV58607066; called by muse, mutect2
- PPM1L | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV55566449, COSV55570748; called by muse, mutect2
- PPP2R1B | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV59253913; called by muse, mutect2, varscan2
- PPP2R5C | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 81/548 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.281); catalogued as COSV58273209; called by muse, varscan2
- PRDM10 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.458); catalogued as COSV58802597; called by muse, mutect2, varscan2
- PRDM13 | c.1830C>G p.F610L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV65029845, COSV65030252; called by muse, mutect2, varscan2
- PRDM2 | c.3595G>C p.E1199Q | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52450076; called by muse, mutect2
- PRDM9 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV57004487; called by muse, mutect2, varscan2
- PREX1 | c.2922C>G p.I974M | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV64253715; called by muse, mutect2, varscan2
- PRKAR1B | c.1111C>A p.Q371K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100816515, COSV64319156; called by muse, varscan2
- PRKCB | c.784G>C p.G262R | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV57787563, COSV57793884; called by muse, mutect2
- PRMT7 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs753947184, COSV59834142; called by muse, mutect2, varscan2
- PRMT9 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1161459556, COSV59360306, COSV59361389; called by muse, mutect2
- PROKR2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773364376, COSV54085515; called by muse, mutect2, varscan2
- PRRC2C | c.2008C>T p.Q670* (on ENST00000367742; = p.Q668* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 21/564 reads (4%) | catalogued as COSV58907965; called by muse, mutect2
- PRSS12 | c.2588C>G p.S863* | Nonsense Mutation (SNP) | VAF 65/162 reads (40%) | catalogued as COSV56607631; called by muse, mutect2, varscan2
- PSG1 | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 87/503 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54952596; called by muse, varscan2
- PSG5 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV61654589; called by muse, mutect2, varscan2
- PSIP1 | c.1211G>C p.R404P | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV66254784, COSV66255077; called by muse, mutect2, varscan2
- PSMD3 | c.1446C>A p.F482L | Missense Mutation (SNP) | VAF 62/418 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52858491; called by muse, mutect2, varscan2
- PTBP2 | c.1066G>C p.E356Q (on ENST00000426398 / NM_001300986.2; = p.E348Q on NM_021190.4) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as COSV64625343; called by muse, mutect2, varscan2
- PTPN13 | c.5422C>T p.Q1808* (on ENST00000411767 / NM_080683.3; = p.Q1789* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV57411018; called by muse, mutect2, varscan2
- PTPRF | c.4380T>G p.C1460W | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63446393; called by muse, mutect2, varscan2
- PTPRN2 | c.2356C>T p.R786W | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201790422, COSV101234354, COSV67026755; called by muse, mutect2, varscan2
- PTPRN2 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373081454; called by muse, mutect2, varscan2
- PTPRO | c.2921A>G p.Y974C (on ENST00000281171 / NM_030667.3; = p.Y946C on NM_002848.4) | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55514732; called by muse, mutect2, varscan2
- PTPRS | c.1202G>C p.W401S | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.593); catalogued as COSV53625968, COSV53628543; called by muse, mutect2
- PWWP3A | c.349G>C p.D117H (on ENST00000627377; = p.D116H on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.424); catalogued as COSV60903094; called by muse, mutect2, varscan2
- PWWP3A | c.587G>C p.G196A (on ENST00000627377; = p.G195A on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.121); catalogued as COSV60903102; called by muse, mutect2, varscan2
- PWWP3B | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61800499; called by muse, mutect2, varscan2
- PXDNL | c.3903C>A p.D1301E | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62477590; called by muse, mutect2, varscan2
- PXYLP1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs573740092, COSV53891711; called by muse, mutect2, varscan2
- RAB33A | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV57062415; called by muse, mutect2, varscan2
- RAD1 | c.848G>C p.*283Sext*2 | Nonstop Mutation (SNP) | VAF 12/177 reads (7%) | catalogued as COSV57715429; called by muse, mutect2
- RAD51AP2 | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs1191191413, COSV67587375, COSV67588476; called by muse, varscan2
- RANBP2 | c.8651C>T p.S2884L | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV51703548; called by muse, mutect2, varscan2
- RANBP9 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 20/347 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50582693; called by muse, mutect2
- RAP1GAP | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51574431; called by muse, mutect2, varscan2
- RAPGEF1 | c.1482G>C p.Q494H | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV64700528; called by muse, mutect2
- RAPGEF4 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 75/426 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs757476344, COSV51399996; called by muse, mutect2, varscan2
- RARS2 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV65761701; called by muse, mutect2
- RASA1 | c.2691-2A>G p.X897_splice | Splice Site (SNP) | VAF 37/78 reads (47%) | catalogued as COSV57197958; called by muse, mutect2, varscan2
- RASA2 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 161/477 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV53937816, COSV53942611; called by muse, mutect2, varscan2
- RASAL1 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55657517; called by muse, mutect2
- RAVER1 | c.1196C>G p.S399* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV53345029; called by muse, mutect2, varscan2
- RAVER1 | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50329412; called by muse, mutect2
- RBM11 | c.713A>G p.D238G | Missense Mutation (SNP) | VAF 84/435 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68748203; called by muse, mutect2, varscan2
- RGL2 | c.1597T>C p.W533R | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65842562; called by muse, mutect2, varscan2
- RHOBTB2 | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs763030083, COSV52392974; called by muse, mutect2, varscan2
- RIC1 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as rs765742639, COSV52611634; called by muse, mutect2, varscan2
- RIMKLA | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.055); catalogued as COSV68909842; called by muse, mutect2
- RIPOR1 | c.2847G>T p.R949S (on ENST00000379312 / NM_001193522.2; = p.R945S on NM_024519.4) | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.221); catalogued as COSV50233922; called by muse, mutect2
- RNF115 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs186281231, COSV65165090; called by muse, mutect2, varscan2
- RNF207 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367951949, COSV65007894; called by muse, mutect2, varscan2
- RNF41 | c.753C>A p.H251Q | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61504646; called by muse, mutect2, varscan2
- RNF6 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60419537; called by muse, mutect2
- ROS1 | c.6886G>A p.E2296K | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs761155034, COSV63857239; called by muse, mutect2, varscan2
- ROS1 | c.2213A>G p.E738G | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); catalogued as COSV63857250; called by muse, mutect2, varscan2
- RP1 | c.4963C>T p.Q1655* | Nonsense Mutation (SNP) | VAF 75/471 reads (16%) | catalogued as COSV55118307; called by muse, mutect2, varscan2
- RPAP1 | c.3631T>A p.Y1211N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58540614; called by muse, mutect2, varscan2
- RPAP3 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 124/621 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs768816369, COSV50042185; called by muse, mutect2, varscan2
- RPH3A | c.622G>C p.D208H (on ENST00000389385 / NM_001143854.2; = p.D204H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.143); catalogued as COSV66991912; called by muse, mutect2, varscan2
- RPS18 | c.411G>C p.K137N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV65851871; called by muse, mutect2, varscan2
- RREB1 | c.4530G>T p.R1510S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58560554; called by muse, mutect2, varscan2
- RSBN1 | c.2058C>G p.F686L | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV54733487; called by muse, varscan2
- RSBN1L | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 14/465 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV58506432; called by muse, mutect2
- RTL5 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 42/97 reads (43%) | catalogued as COSV65454037; called by muse, mutect2, varscan2
- RTN1 | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV50731625; called by muse, mutect2, varscan2
- RTP2 | c.71C>A p.A24E | Missense Mutation (SNP) | VAF 73/694 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.239); catalogued as COSV100832942, COSV64079200; called by muse, mutect2, varscan2
- RUSC1 | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV52740855, COSV52740954; called by muse, mutect2, varscan2
- RYR1 | c.12667G>A p.E4223K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as COSV62102222; called by muse, mutect2, varscan2
- RYR3 | c.2158T>G p.W720G | Missense Mutation (SNP) | VAF 109/467 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66798023; called by muse, mutect2, varscan2
- SAMD7 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV59419724; called by muse, mutect2, varscan2
- SAMD9L | c.599A>T p.K200I | Missense Mutation (SNP) | VAF 125/413 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59082943; called by muse, mutect2, varscan2
- SBK2 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV60014824; called by muse, mutect2, varscan2
- SBNO2 | c.3049_3051del p.E1017del | In Frame Del (DEL) | VAF 26/52 reads (50%) | catalogued as rs747417026; called by pindel, varscan2
- SCG5 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs201757263, COSV55707160; called by muse, mutect2, varscan2
- SCN1A | c.5664G>C p.Q1888H (on ENST00000303395 / NM_001202435.3; = p.Q1877H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV57666973, COSV57676226; called by muse, mutect2, varscan2
- SCN8A | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.98); catalogued as COSV61977476; called by muse, mutect2
- SCP2 | c.856A>T p.R286* | Nonsense Mutation (SNP) | VAF 38/229 reads (17%) | catalogued as COSV65261581; called by muse, mutect2, varscan2
- SDK2 | c.5763G>C p.Q1921H | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV66190265; called by muse, mutect2, varscan2
- SEC14L5 | c.1863del p.S622Afs*14 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs764657044; called by mutect2, pindel, varscan2
- SEC31A | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV58876367; called by muse, mutect2, varscan2
- SEC63 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 106/294 reads (36%) | catalogued as COSV64600730, COSV64601435; called by muse, mutect2, varscan2
- SELL | c.936G>C p.K312N (on ENST00000650983; = p.K299N on NM_000655.5) | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52551894, COSV52552999; called by muse, mutect2, varscan2
- SELP | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55254314; called by muse, mutect2, varscan2
- SEMA3C | c.1643+1G>A p.X548_splice | Splice Site (SNP) | VAF 15/279 reads (5%) | catalogued as COSV54849811; called by muse, mutect2
- SEMA4F | c.1411C>G p.Q471E | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV60284048; called by muse, mutect2, varscan2
- SEPTIN4 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 12/301 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); catalogued as COSV58728367; called by muse, mutect2
- SFN | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59433648; called by muse, mutect2
- SFTPA1 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 62/369 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV64867366; called by muse, mutect2, varscan2
- SGSM1 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV68511462; called by muse, mutect2, varscan2
- SGSM3 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763920663, COSV50653414; called by muse, mutect2, varscan2
- SH2D2A | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 133/493 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.069); catalogued as COSV63885047, COSV63885457; called by muse, mutect2, varscan2
- SI | c.2318G>A p.W773* | Nonsense Mutation (SNP) | VAF 102/283 reads (36%) | catalogued as COSV52286660; called by muse, mutect2, varscan2
- SIAH1 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV53523722; called by muse, mutect2
- SKAP1 | c.866G>C p.R289P | Missense Mutation (SNP) | VAF 149/441 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61148448; called by muse, mutect2, varscan2
- SLC12A1 | c.1699A>G p.I567V | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66796800; called by muse, mutect2, varscan2
- SLC12A1 | c.3052C>A p.P1018T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV66796806; called by muse, mutect2, varscan2
- SLC12A2 | c.1218C>G p.I406M | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV52473282; called by muse, mutect2, varscan2
- SLC13A1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV52013580; called by muse, mutect2, varscan2
- SLC13A3 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV51716066; called by muse, mutect2
- SLC15A3 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57172386; called by muse, varscan2
- SLC18B1 | c.697G>C p.A233P | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as COSV51595090; called by muse, mutect2, varscan2
- SLC25A40 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV62020715; called by muse, mutect2, varscan2
- SLC26A8 | c.2374G>A p.V792M | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs115071158; called by muse, mutect2, varscan2
- SLC2A5 | c.1483C>A p.P495T | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.81); catalogued as COSV66237344; called by muse, mutect2
- SLC30A4 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as rs754695518, COSV56006630; called by muse, mutect2, varscan2
- SLC46A2 | c.1208C>G p.S403C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV65290166; called by muse, mutect2, varscan2
- SLC49A4 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 104/284 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV53746286, COSV53748397; called by muse, mutect2, varscan2
- SLC4A1AP | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV58135868; called by muse, mutect2
- SLC5A5 | c.1113C>G p.I371M | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV55833963; called by muse, mutect2
- SLC5A9 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52584363; called by muse, mutect2, varscan2
- SLC6A15 | c.2060C>G p.S687C | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57025792; called by muse, mutect2, varscan2
- SLIT1 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV56592781; called by muse, mutect2, varscan2
- SMC5 | c.2534C>T p.T845I | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.683); catalogued as COSV63193889; called by muse, mutect2, varscan2
- SMCHD1 | c.1937G>A p.G646E | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55261300; called by muse, mutect2
- SMCHD1 | c.4008G>T p.R1336S | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV55261349; called by muse, mutect2
- SMG1 | c.9298C>T p.Q3100* | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as COSV67172911; called by muse, mutect2, varscan2
- SMYD5 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 56/264 reads (21%) | catalogued as COSV50265243; called by muse, mutect2
- SNAP25 | c.603G>C p.K201N | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV54773624; called by muse, mutect2, varscan2
- SNX10 | c.384A>T p.E128D | Missense Mutation (SNP) | VAF 161/316 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as COSV58401546; called by muse, mutect2, varscan2
- SORCS1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV53880380, COSV53904652; called by muse, mutect2
- SP6 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.087); catalogued as COSV60618396; called by muse, mutect2, varscan2
- SPAG17 | c.2478G>A p.M826I | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60458494; called by muse, mutect2, varscan2
- SPAG9 | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56235602, COSV56238428; called by muse, mutect2, varscan2
- SPTA1 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 53/328 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV100935435, COSV63755992; called by muse, mutect2, varscan2
- SPTBN5 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as rs1178923626, COSV58023582; called by muse, mutect2, varscan2
- SSTR5 | c.1017G>C p.R339S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53512734; called by muse, mutect2
- ST8SIA4 | c.1037G>C p.R346T | Missense Mutation (SNP) | VAF 11/118 reads (9%) | PolyPhen benign (0.078); catalogued as COSV51512494; called by muse, mutect2
- STAC2 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61065994; called by muse, mutect2
- SUGP2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 32/602 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs752911125, COSV54182222; called by muse, mutect2
- SULT1C2 | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV52265636; called by muse, mutect2, varscan2
- SUN2 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.368); catalogued as COSV53305099; called by muse, mutect2, varscan2
- SYN3 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV60502072, COSV60510898, COSV60511090; called by muse, mutect2, varscan2
- SYNDIG1 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1418311992, COSV65233241, COSV65234846; called by muse, mutect2, varscan2
- SYNE1 | c.9189G>T p.Q3063H (on ENST00000367255 / NM_182961.4; = p.Q3070H on NM_033071.3) | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV55025209; called by muse, mutect2, varscan2
- SYNE2 | c.8461A>T p.K2821* | Nonsense Mutation (SNP) | VAF 11/126 reads (9%) | catalogued as COSV59956918; called by muse, mutect2
- SYNE2 | c.14008G>A p.E4670K | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1330613504, COSV59941985, COSV59956923; called by muse, mutect2, varscan2
- SYNE3 | c.1539G>C p.E513D | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV62080574; called by muse, varscan2
- SZT2 | c.8641G>A p.E2881K (on ENST00000634258 / NM_001365999.1; = p.E2824K on NM_015284.4) | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as COSV65171349; called by muse, mutect2, varscan2
- TAAR2 | c.229C>G p.P77A (on ENST00000367931 / NM_001033080.1; = p.P32A on NM_014626.3) | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759731776, COSV51579433; called by muse, mutect2, varscan2
- TAPBP | c.68C>G p.A23G | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV56470857; called by muse, mutect2, varscan2
- TAS1R1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.338); catalogued as COSV60229088; called by muse, mutect2, varscan2
- TBC1D1 | c.3364G>T p.E1122* | Nonsense Mutation (SNP) | VAF 37/118 reads (31%) | catalogued as COSV54722241; called by muse, mutect2, varscan2
- TBX22 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64786441, COSV64786765; called by muse, mutect2, varscan2
- TCEAL5 | c.510G>C p.W170C | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV65503199; called by muse, mutect2, varscan2
- TCF4 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61896759; called by muse, mutect2
- TEFM | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58976183; called by muse, mutect2
- TEKT4 | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs143585686; called by muse, mutect2, varscan2
- TENM4 | c.8283G>C p.M2761I | Missense Mutation (SNP) | VAF 96/965 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV53643102; called by muse, mutect2, varscan2
- TEP1 | c.3219C>A p.R1073= | Splice Region (SNP) | VAF 93/505 reads (18%) | catalogued as COSV52995296; called by muse, mutect2, varscan2
- TET1 | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV65386274; called by muse, mutect2, varscan2
- TEX13B | c.454C>A p.H152N | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV57203272, COSV57203471; called by muse, mutect2, varscan2
- TFAP2B | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.332); catalogued as COSV53829090; called by muse, mutect2
- TFCP2L1 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV55292590, COSV99748476; called by muse, mutect2
- TFIP11 | c.2174C>A p.P725Q | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53226798; called by muse, mutect2
- TGFB1I1 | c.964G>C p.D322H (on ENST00000394863 / NM_001042454.3; = p.D305H on NM_015927.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV62358430; called by muse, mutect2
- TGFB2 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100859913, COSV65110021; called by muse, mutect2, varscan2
- THEMIS | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV64069337, COSV64072160; called by muse, mutect2, varscan2
- THG1L | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as COSV51452481; called by muse, mutect2, varscan2
- THRA | c.35C>G p.S12* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV52844516; called by muse, mutect2, varscan2
- THRAP3 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs780723624, COSV63566679; called by muse, mutect2, varscan2
- THSD7A | c.2946G>T p.L982F | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.342); catalogued as COSV70264266; called by muse, mutect2
- TLN2 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs780454196, COSV60891714; called by muse, mutect2
- TMEM132A | c.2843C>G p.S948* (on ENST00000453848 / NM_178031.3; = p.S949* on NM_017870.4) | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV50011385; called by muse, mutect2, varscan2
- TMEM132D | c.3254G>A p.C1085Y | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs751593339, COSV67160325, COSV67160978; called by muse, mutect2, varscan2
- TMEM135 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 77/444 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59702583; called by muse, mutect2, varscan2
- TMEM192 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.209); catalogued as rs553668773, COSV100121965, COSV60585545; called by muse, mutect2, varscan2
- TMEM53 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV59191086; called by muse, mutect2, varscan2
- TMPRSS6 | c.2299T>C p.F767L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60980655; called by muse, mutect2
- TNIP1 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV59308170; called by muse, mutect2, varscan2
- TNRC6B | c.5179C>G p.L1727V (on ENST00000454349 / NM_001162501.2; = p.L1617V on NM_015088.3) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs746928822, COSV57300354; called by muse, mutect2, varscan2
- TNS1 | c.3934C>T p.P1312S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV50720544; called by muse, mutect2
- TPCN2 | c.1748G>A p.G583D | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV53730776; called by muse, mutect2
- TPP1 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV54994620; called by muse, mutect2, varscan2
- TRANK1 | c.5829C>A p.F1943L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57155180, COSV57155548; called by muse, mutect2, varscan2
385 further variants in this file (109 protein-altering or splice-affecting, 247 silent, 29 other) are not listed here.
